Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A88V, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A88V-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 1
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

A -year-old male recently diagnosed with phase 2 distal esophageal adenocarcinoma. Patient has elected to forego treatment with radiation therapy proceeding directly with esophagectomy.

PROCEDURE:

VERIFIED BY:

1. "Proximal stomach and esophagus." Received in formalin in a medium container is a 6.2 cm long portion of distal esophagus. There is a 8.2 x 4.3 x 1.7 cm portion of proximal stomach attached. The adventitia is red-tan and ragged. The esophagus is tan-grey and prominently folded. At the esophageal gastric junction is a 2.0 x 1.3 x 1.2 cm, granular, ulcerative, tan tumor that is 5.7 cm away from the proximal margin and 2.6 cm away from the distal margin. The midpoint of the tumor is at the esophageal gastric junction. Tumor has a maximum depth of 0.6 cm and extends into the paraesophageal adipose. Also possible lymph nodes are identified ranging up to 1.1 cm.
- 1A-B. Tumor to adjacent proximal and distal.
- 1C-D. Tumor to deep.
- 1F-G. Esophageal gastric junction.
- 1H. Multiple proximal lymph nodes.
- 1I. One bisected possible lymph node.
2. "Cervical esophageal margin." Received in formalin in a small container is a 0.6 cm long portion of esophagus. Submucosal hemorrhage is noted. No other abnormalities are noted. Staple line retained.

PROCEDURE:

VERIFIED BY:

ESOPHAGUS CARCINOMA

LOCATION: Lower

SIZE: 2.0 cm

TYPE OF CARCINOMA: Adenocarcinoma

DEPTH OF INVASION: Adventitia

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 1/15

DISTANT METASTASIS: Unknown

ID# 3
Adenocarcinoma, NOS 8140/3
Site ^{CCF} Distal third esophagus C15.5
path
Lower third esophagus C15.5
JAJ 11/2/13

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 2
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

RESECTION MARGIN INVOLVED: No

T3 N1 Mx

PROCEDURE:

VERIFIED BY:

1-2. Esophagus, resection: Adenocarcinoma at the gastroesophageal junction, invading to the adventitia. Metastatic carcinoma in one out of fifteen lymph nodes. Resection margins negative for carcinoma. Please see template for details.

I, , the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Major Malignancy History		

Source: NCI Genomic Data Commons file 0cba55bf-537c-4715-acdf-fe94b3b48fb7 (TCGA-L5-A88V.1B9197D9-0072-44D2-A28E-F23C2402F765.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).